Surgical pathology report (de-identified scan), TCGA case TCGA-58-A46L, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-58-A46L-01A (Primary Tumor).

ICD-O-3

Carcinoma, Squamous cell,
basaloid 8083/3

Site: lung, upper lobe

9-5-12

RD

C34.1

Pathology Report-Summary:

Material:

lung, right, upper lobe: 15.0 x 11.0 x 6.5 cm

tumor: 8.0 x 5.0 x 7.5 cm

Diagnosis:

Squamous Cell Carcinoma, basaloid

Infiltration of pleura visceralis

pT2, pN2 (1/31), pMx, G3

Pathologist:

HI/AA Discrepancy		X
Reviewer (initials)	Date Reviewed: 8/21/12	

EWL

Source: NCI Genomic Data Commons file babced78-7160-47a3-b8bc-4ae4e4c81ae6 (TCGA-58-A46L.56894615-979E-4A89-B6D4-F6639C0188FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).